Gene-level copy-number profile of tumor specimen C3L-06716-01 from CPTAC case C3L-06716, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G4; Age at diagnosis: 69.1 years (25,221 days).
Specimen C3L-06716-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b03cbeff-c6bf-453b-96e8-052f86fb2ada.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06716-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/4883ccc6-50a3-46c2-bc73-03a512854944

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 8,085; copy number 2: 45,785; copy number 3: 4,676; copy number 4: 357; copy number 5: 5.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:1,176,790–1,177,012, 1 gene: COX6CP3.
- chr21:44,300,051–44,330,221, 2 genes (within-gene range 0–2): PFKL, AP001062.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:142,023,160–142,847,432, 5 genes, copy number 5: INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1.

Autosomal genes at a single copy (total copy number 1): 5,229. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
